Somatic mutation profile of tumor specimen C3N-02030-01 (aliquot CPT0133760082) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1292ef5a-55c1-4886-8e1c-07a23862269f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ff6b9fa-1b6e-42d3-8892-de18fd4ab490

The open-access MAF lists 663 somatic variants for this specimen: 455 protein-altering or splice-affecting, 127 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 312, Silent 127, Frame Shift Del 78, Intron 51, Nonsense Mutation 24, Frame Shift Ins 23, 3'UTR 11, Splice Site 8, 5'UTR 7, RNA 5, In Frame Del 5, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 112/359 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 74/138 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 115/402 reads (29%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 86/360 reads (24%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 50/204 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 221/472 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 112/300 reads (37%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 47/126 reads (37%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 77/202 reads (38%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ABI3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs770714352; called by muse, mutect2, varscan2
- ACTN4 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758778538; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- AGA | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV52806092; called by muse, mutect2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 154/253 reads (61%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 51/250 reads (20%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ALG5 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53504362; called by muse, mutect2
- AMER1 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV57654677; called by muse, mutect2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 194/504 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 48/190 reads (25%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 79/285 reads (28%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 30/153 reads (20%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CALHM1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373850573; called by muse, mutect2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2, varscan2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 212/572 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 24/93 reads (26%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP46 | c.4868C>T p.S1623L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1018417455; called by muse, mutect2, varscan2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 104/386 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 34/102 reads (33%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 161/493 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2, varscan2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- CYP2D7 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs764888846; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 171/410 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCAF13 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs868133848; called by muse, mutect2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 136/343 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 141/371 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 140/504 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DNAH5 | c.4389G>A p.W1463* | Nonsense Mutation (SNP) | VAF 20/387 reads (5%) | catalogued as rs758550738, COSV54255499; called by muse, mutect2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 47/129 reads (36%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- DTX1 | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 13/253 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs890968014; called by muse, mutect2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- EP400 | c.8863G>A p.V2955I | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as rs747186520, COSV57779724; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 151/400 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by muse, mutect2, varscan2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 234/651 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 164/772 reads (21%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FOXE1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64300120; called by muse, mutect2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 85/334 reads (25%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- GPR50 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs760818840; called by muse, mutect2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 42/97 reads (43%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNA3 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1234028653; called by muse, mutect2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 61/185 reads (33%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM5A | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV66990391; called by muse, mutect2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, mutect2, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2
- MACF1 | c.22075G>A p.G7359R (on ENST00000372915; = p.G5404R on NM_012090.5) | Missense Mutation (SNP) | VAF 5/100 reads (5%) | catalogued as COSV99242591; called by muse, mutect2
- MAGI2 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62640251; called by muse, mutect2, varscan2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 37/134 reads (28%) | catalogued as rs1321319432; called by mutect2, pindel
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 104/267 reads (39%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MTFMT | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs1179897414; called by muse, mutect2
- MXRA5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs368706975, COSV54224299; called by muse, mutect2
- MYEOV | c.869del p.P290Qfs*48 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | catalogued as COSV58294423; called by mutect2, pindel, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 173/491 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NCOA5 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 37/510 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774397965, COSV51643562; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 29/196 reads (15%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NISCH | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1017181336, COSV61898614; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 168/502 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- OBSL1 | c.5045G>A p.R1682H | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs1479080818; called by muse, mutect2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 41/109 reads (38%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 78/469 reads (17%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR12D2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs752585138, COSV65828725; called by muse, mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 160/410 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 115/338 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 42/290 reads (14%) | catalogued as COSV100967422; called by mutect2, pindel, varscan2
- PARD3B | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV62502529; called by muse, mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | catalogued as rs759495724; called by mutect2, varscan2
- PEAK1 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 17/303 reads (6%) | catalogued as rs538475609, COSV56935136; called by muse, mutect2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 44/148 reads (30%) | catalogued as rs755089774; called by pindel, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 106/369 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 212/567 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 175/502 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | catalogued as rs1234606471; called by mutect2, varscan2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs763290832; called by mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SEMA6C | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 18/495 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214468588, COSV59002376; called by muse, mutect2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 39/103 reads (38%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 88/338 reads (26%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SLITRK4 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 15/285 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs371255197, COSV62023616; called by muse, mutect2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | catalogued as rs763364024; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 60/262 reads (23%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 54/174 reads (31%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 148/395 reads (37%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 98/645 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 77/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TELO2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776490787; called by muse, mutect2
- TELO2 | c.933G>A p.T311= | Splice Region (SNP) | VAF 12/176 reads (7%) | catalogued as rs1167542668; called by muse, mutect2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by muse, mutect2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 144/421 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 99/256 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 58/188 reads (31%) | catalogued as rs770800449; called by mutect2, varscan2
- TRAPPC12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV60845878; called by muse, mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 158/399 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRIOBP | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 20/176 reads (11%) | catalogued as rs1328461856, CM154690; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TTLL1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1569403339, COSV56740189; called by muse, mutect2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- UGT2A1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745764251; called by muse, mutect2, varscan2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2
- WDR4 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374998; called by muse, mutect2
- WDR81 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as rs770277633; called by muse, mutect2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 129/420 reads (31%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 72/213 reads (34%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFHX2 | c.4709G>A p.R1570Q | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as rs1004295168; called by muse, mutect2
- ZKSCAN2 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV60156375; called by muse, mutect2, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 86/259 reads (33%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ABCB8 | c.1193G>A p.G398D (on ENST00000297504 / NM_001282291.2; = p.G381D on NM_007188.5) | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 210/559 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 163/491 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 63/241 reads (26%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 37/118 reads (31%) | called by mutect2, pindel, varscan2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- APBA2 | c.1918-1G>T p.X640_splice | Splice Site (SNP) | VAF 61/433 reads (14%) | called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 50/227 reads (22%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 53/171 reads (31%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 105/463 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CA6 | c.501+2T>C p.X167_splice | Splice Site (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- CACNA2D1 | c.2711G>A p.C904Y (on ENST00000356253 / NM_001366867.1; = p.C892Y on NM_000722.4) | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 34/137 reads (25%) | called by mutect2, pindel, varscan2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 33/124 reads (27%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 98/250 reads (39%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 57/153 reads (37%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 120/375 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORIN | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); called by muse, mutect2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 74/263 reads (28%) | called by pindel, varscan2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 43/142 reads (30%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 132/329 reads (40%) | called by muse, mutect2, varscan2
- CYP2U1 | c.119G>A p.C40Y | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DAAM1 | c.2663+4_2663+7del p.X888_splice | Splice Site (DEL) | VAF 13/68 reads (19%) | called by pindel, varscan2
- DCAF4 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 103/343 reads (30%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 116/651 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 98/365 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DMXL2 | c.7517+2T>A p.X2506_splice | Splice Site (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- DPH2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 69/231 reads (30%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 78/241 reads (32%) | called by mutect2, pindel, varscan2
- EEPD1 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | called by mutect2, pindel, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERAP1 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 39/533 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 48/139 reads (35%) | called by mutect2, pindel, varscan2
- EVC2 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 17/558 reads (3%) | called by muse, mutect2
- EXOC4 | c.33A>C p.R11S | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.264); called by muse, mutect2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 199/535 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 58/233 reads (25%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 86/302 reads (28%) | called by mutect2, pindel, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 46/182 reads (25%) | called by mutect2, pindel, varscan2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 12/56 reads (21%) | called by muse, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 89/269 reads (33%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 108/430 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GAS2L1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GMNN | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 174/842 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 101/364 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 77/212 reads (36%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 48/234 reads (21%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BC12 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- HDHD2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); called by muse, mutect2
- HEATR3 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 18/227 reads (8%) | called by muse, mutect2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 48/208 reads (23%) | called by pindel, varscan2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 177/491 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 104/284 reads (37%) | called by mutect2, pindel, varscan2
- IL6ST | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 35/85 reads (41%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 17/158 reads (11%) | called by mutect2, pindel
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 166/436 reads (38%) | called by mutect2, varscan2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 51/167 reads (31%) | called by mutect2, pindel, varscan2
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 98/318 reads (31%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KDM4B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KEL | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 57/424 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 165/946 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 54/148 reads (36%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 120/296 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMA3 | c.5044G>T p.G1682* (on ENST00000313654 / NM_198129.4; = p.G73* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 90/261 reads (34%) | called by mutect2, pindel, varscan2
- LBR | c.1806C>A p.Y602* | Nonsense Mutation (SNP) | VAF 22/364 reads (6%) | called by muse, mutect2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 34/88 reads (39%) | called by mutect2, pindel, varscan2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 86/384 reads (22%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 163/451 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFN2 | c.2070-7T>C | Splice Region (SNP) | VAF 59/444 reads (13%) | called by muse, mutect2, varscan2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MPP3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYF6 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NCDN | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 38/169 reads (22%) | called by mutect2, pindel, varscan2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 87/266 reads (33%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 31/131 reads (24%) | called by mutect2, pindel, varscan2
- OR2A5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- OR2C1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 26/62 reads (42%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 105/341 reads (31%) | called by mutect2, pindel, varscan2
- OTUD7A | c.2654G>A p.C885Y (on ENST00000307050 / NM_001382637.1; = p.C878Y on NM_130901.3) | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.093); called by muse, mutect2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 47/151 reads (31%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 140/385 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 193/547 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 114/389 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PHACTR4 | c.2009C>T p.A670V (on ENST00000373839 / NM_001350159.2; = p.A680V on NM_023923.4) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 66/176 reads (38%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 138/385 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PNMA8B | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 130/364 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP1R16A | c.1498A>G p.R500G | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 59/271 reads (22%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 47/181 reads (26%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 127/375 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 93/281 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- RALGAPB | c.4142+2T>C p.X1381_splice | Splice Site (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBL1 | c.824T>G p.I275S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 28/111 reads (25%) | called by mutect2, pindel, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RTL9 | c.1247T>C p.M416T | Missense Mutation (SNP) | VAF 11/339 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- SAGE1 | c.833dup p.N278Kfs*25 | Frame Shift Ins (INS) | VAF 26/157 reads (17%) | called by mutect2, pindel, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 219/585 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 67/287 reads (23%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 52/78 reads (67%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 227/686 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | called by mutect2, varscan2
- SIK3 | c.2311C>T p.P771S (on ENST00000445177 / NM_001366686.2; = p.P729S on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SLC22A25 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCA4 | c.3697A>G p.M1233V | Missense Mutation (SNP) | VAF 51/592 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- SMARCAD1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMYD5 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SST | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 18/403 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SUSD2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 86/293 reads (29%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 153/458 reads (33%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 60/192 reads (31%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 235/645 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SZT2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBC1D22B | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); called by muse, mutect2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TENM3 | c.7903C>T p.R2635C | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TERB1 | c.365_368del p.S122Ffs*18 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 56/176 reads (32%) | called by mutect2, pindel
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TLNRD1 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 75/271 reads (28%) | called by mutect2, pindel, varscan2
- TMEM200B | c.451del p.V151Cfs*31 | Frame Shift Del (DEL) | VAF 26/294 reads (9%) | called by mutect2, pindel
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 89/383 reads (23%) | called by mutect2, pindel, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 44/121 reads (36%) | called by pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 80/230 reads (35%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 64/177 reads (36%) | PolyPhen probably damaging (0.994); called by muse, varscan2
- UBE3B | c.183del p.F61Lfs*44 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASHC2A | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 46/140 reads (33%) | called by mutect2, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 50/159 reads (31%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- ZNF292 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 45/150 reads (30%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 127/315 reads (40%) | called by muse, mutect2, varscan2
- AKAP13 | c.3813T>C p.T1271= | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- ANO1 | c.903G>A p.L301= | Silent (SNP) | VAF 7/179 reads (4%) | catalogued as COSV60287763; called by muse, mutect2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGEF17 | c.5055G>A p.E1685= | Silent (SNP) | VAF 53/141 reads (38%) | catalogued as rs1016884567; called by muse, mutect2, varscan2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 79/207 reads (38%) | called by muse, mutect2, varscan2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 156/434 reads (36%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CA8 | c.480G>A p.P160= | Silent (SNP) | VAF 32/532 reads (6%) | catalogued as rs537454715; called by muse, mutect2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 69/228 reads (30%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 73/219 reads (33%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 52/216 reads (24%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- CD53 | c.30G>A p.K10= | Silent (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 202/542 reads (37%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 59/159 reads (37%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 81/250 reads (32%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 137/391 reads (35%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 67/171 reads (39%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs771383564; called by muse, mutect2
- DHX16 | c.1398C>A p.A466= | Silent (SNP) | VAF 39/372 reads (10%) | called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 63/175 reads (36%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 128/533 reads (24%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1858C>T p.L620= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- EPB41L4B | c.1381C>A p.R461= | Silent (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- ETHE1 | c.312C>T p.R104= | Silent (SNP) | VAF 12/347 reads (3%) | called by muse, mutect2
- FAT2 | c.5760T>C p.P1920= | Silent (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 77/272 reads (28%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 69/504 reads (14%) | called by muse, mutect2, varscan2
- GTF2F1 | c.879G>A p.Q293= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as COSV66725853; called by muse, mutect2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 82/252 reads (33%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 66/237 reads (28%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HCRTR1 | c.615C>T p.R205= | Silent (SNP) | VAF 37/138 reads (27%) | called by muse, mutect2, varscan2
- HDHD5 | c.1083G>A p.V361= (on ENST00000336737 / NM_033070.3; = p.V331= on NM_017829.5) | Silent (SNP) | VAF 16/428 reads (4%) | called by muse, mutect2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HEPACAM | c.381C>T p.T127= | Silent (SNP) | VAF 24/298 reads (8%) | catalogued as rs766390439, COSV53432420; called by muse, mutect2
- HIRA | c.1809G>A p.R603= | Silent (SNP) | VAF 32/303 reads (11%) | catalogued as rs762213339; called by muse, mutect2, varscan2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 77/196 reads (39%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 123/342 reads (36%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 42/124 reads (34%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 102/279 reads (37%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 66/162 reads (41%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 93/365 reads (25%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIF7 | c.786G>A p.T262= | Silent (SNP) | VAF 34/427 reads (8%) | catalogued as rs1054963355, COSV67998466; called by muse, mutect2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 28/226 reads (12%) | called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 78/172 reads (45%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 80/351 reads (23%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs1195603578; called by mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 200/602 reads (33%) | called by muse, mutect2, varscan2
- LZTR1 | c.1425G>A p.T475= | Silent (SNP) | VAF 21/282 reads (7%) | catalogued as rs140414846; called by muse, mutect2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 74/234 reads (32%) | called by muse, mutect2, varscan2
- MED13 | c.5769T>C p.F1923= | Silent (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NKX2-5 | c.300C>T p.P100= | Silent (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- NLGN2 | c.144C>T p.Y48= | Silent (SNP) | VAF 34/344 reads (10%) | catalogued as rs750428123; called by muse, mutect2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 172/521 reads (33%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- NRXN2 | c.297C>T p.A99= | Silent (SNP) | VAF 25/275 reads (9%) | called by muse, mutect2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 138/360 reads (38%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 81/224 reads (36%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 47/197 reads (24%) | catalogued as COSV53370990, COSV53372538; called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 125/348 reads (36%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 120/427 reads (28%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1773C>T p.D591= | Silent (SNP) | VAF 18/686 reads (3%) | catalogued as COSV99169956; called by muse, mutect2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 83/236 reads (35%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PICK1 | c.1161G>A p.E387= | Silent (SNP) | VAF 67/193 reads (35%) | catalogued as rs1266755272; called by mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 126/485 reads (26%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 146/328 reads (45%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POC5 | c.1254A>G p.P418= (on ENST00000428202 / NM_001099271.2; = p.P393= on NM_152408.2) | Silent (SNP) | VAF 25/560 reads (4%) | called by muse, mutect2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 69/321 reads (21%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 51/308 reads (17%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 169/433 reads (39%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 83/224 reads (37%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 78/202 reads (39%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 108/270 reads (40%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RIC8A | c.1071G>A p.L357= (on ENST00000526104 / NM_001286134.1; = p.L363= on NM_021932.5) | Silent (SNP) | VAF 19/237 reads (8%) | called by muse, mutect2
- RNF175 | c.208C>T p.L70= | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- RPS10-NUDT3 | c.120G>A p.V40= | Silent (SNP) | VAF 19/204 reads (9%) | called by muse, mutect2
- SEC63 | c.360T>A p.I120= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV64599356; called by muse, mutect2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 91/293 reads (31%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 216/624 reads (35%) | called by muse, varscan2
- SLC38A3 | c.1116C>T p.A372= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs776407403; called by muse, mutect2
- SLC39A13 | c.567C>T p.A189= | Silent (SNP) | VAF 24/536 reads (4%) | catalogued as rs774704127, COSV61521040; called by muse, mutect2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 91/241 reads (38%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 86/251 reads (34%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/120 reads (39%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 84/297 reads (28%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SRF | c.888C>A p.S296= | Silent (SNP) | VAF 36/523 reads (7%) | called by muse, mutect2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2
- SULT1E1 | c.645A>G p.S215= | Silent (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 125/359 reads (35%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 72/267 reads (27%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 77/180 reads (43%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 103/259 reads (40%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 68/179 reads (38%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 68/223 reads (30%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 152/457 reads (33%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 66/393 reads (17%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 127/376 reads (34%) | called by muse, mutect2, varscan2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 133/345 reads (39%) | called by muse, mutect2, varscan2
- ZBTB7C | c.1587C>T p.S529= | Silent (SNP) | VAF 14/213 reads (7%) | called by muse, mutect2
- ZNF239 | c.303C>T p.S101= | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as rs1326110759; called by muse, mutect2, varscan2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 59/161 reads (37%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 66/226 reads (29%) | called by muse, mutect2, varscan2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 41/159 reads (26%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 98/208 reads (47%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 101/277 reads (36%) | called by muse, mutect2, varscan2
- ADAR | c.2496+35_2496+37del | Intron (DEL) | VAF 22/185 reads (12%) | catalogued as rs779843196; called by pindel, varscan2*
- AK9 | c.1254+19_1254+22del | Intron (DEL) | VAF 10/63 reads (16%) | catalogued as rs770626634; called by mutect2, pindel, varscan2*
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 179/1007 reads (18%) | called by muse, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 101/394 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 29/94 reads (31%) | called by mutect2, pindel
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs1383985581; called by muse, mutect2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 52/222 reads (23%) | called by muse, mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 52/151 reads (34%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 23/90 reads (26%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- COL5A1 | c.3367-41G>A | Intron (SNP) | VAF 16/328 reads (5%) | called by muse, mutect2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 44/426 reads (10%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 108/297 reads (36%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- CYP21A1P | n.1530C>T | RNA (SNP) | VAF 28/585 reads (5%) | catalogued as rs755622648; called by muse, mutect2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 96/350 reads (27%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DDX55 | c.1164+15G>A | Intron (SNP) | VAF 20/126 reads (16%) | catalogued as rs754189427; called by mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 75/239 reads (31%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- DOT1L | c.4606+790C>T | Intron (SNP) | VAF 12/252 reads (5%) | catalogued as rs1231667609; called by muse, mutect2
- EEF1AKMT2 | c.292-45T>G | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 22/70 reads (31%) | catalogued as rs1446348498; called by mutect2, pindel
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 49/138 reads (36%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 45/288 reads (16%) | called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 59/340 reads (17%) | called by muse, mutect2, varscan2
- FMO6P | n.1375G>T | RNA (SNP) | VAF 39/438 reads (9%) | catalogued as rs1462308165; called by muse, mutect2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 80/198 reads (40%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- HDAC5 | c.*69A>C | 3'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, varscan2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 72/229 reads (31%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 61/155 reads (39%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 55/169 reads (33%) | catalogued as COSV67183745; called by mutect2, varscan2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 51/218 reads (23%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 30/185 reads (16%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 18/50 reads (36%) | catalogued as rs767804788; called by muse, mutect2, varscan2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 99/231 reads (43%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MGAT4B | c.720-10C>T | Intron (SNP) | VAF 35/279 reads (13%) | catalogued as rs768415930; called by muse, mutect2, varscan2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 86/220 reads (39%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 4/19 reads (21%) | catalogued as rs746639059; called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 42/282 reads (15%) | catalogued as rs1305952989, COSV58516256; called by muse, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 44/114 reads (39%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 18/86 reads (21%) | catalogued as rs749732874; called by mutect2, pindel
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 64/177 reads (36%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 37/81 reads (46%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- NVL | c.285-15C>A | Intron (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 47/144 reads (33%) | catalogued as rs771823733; called by mutect2, varscan2
- OR7A2P | n.362G>A | RNA (SNP) | VAF 25/208 reads (12%) | catalogued as rs528570028; called by muse, mutect2, varscan2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 152/561 reads (27%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 32/136 reads (24%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 32/116 reads (28%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 56/210 reads (27%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 26/117 reads (22%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- POLM | c.714+75C>A | Intron (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- POPDC2 | c.1009+84del | Intron (DEL) | VAF 8/77 reads (10%) | called by mutect2, varscan2
- PPFIA1 | c.2163+1522del | Intron (DEL) | VAF 16/177 reads (9%) | called by mutect2, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 99/243 reads (41%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 75/439 reads (17%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 67/221 reads (30%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 67/200 reads (34%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 36/262 reads (14%) | called by muse, mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 30/105 reads (29%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 176/547 reads (32%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 90/525 reads (17%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 62/264 reads (23%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNW1 | c.1413-30T>A | Intron (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 63/177 reads (36%) | called by mutect2, pindel, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- TIMP3 | c.-57C>T | 5'UTR (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- TP53AIP1 | c.141+48C>A | Intron (SNP) | VAF 22/216 reads (10%) | catalogued as COSV101513087; called by muse, mutect2, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 53/143 reads (37%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 16/74 reads (22%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 18/113 reads (16%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- ZNF420 | c.*1105A>G | 3'UTR (SNP) | VAF 18/230 reads (8%) | catalogued as rs888810436; called by muse, mutect2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 44/156 reads (28%) | called by mutect2, pindel, varscan2
